Somatic mutation profile of tumor specimen C3L-06193-05 (aliquot CPT0455980009) from CPTAC case C3L-06193, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 47.8 years (17,472 days).
Specimen C3L-06193-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed27eb46-e453-4eed-be5f-14f130dc3921.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06193-31 (Blood Derived Normal), aliquot CPT0456090003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6f7e6db-00cd-45b9-84ac-accfc0912ed2

The open-access MAF lists 218 somatic variants for this specimen: 140 protein-altering or splice-affecting, 68 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 68, Intron 8, Nonsense Mutation 5, 5'Flank 2, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 199/443 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBN1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 92/403 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs794728188, COSV57310667; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1064793345; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC8 | c.1460G>A p.S487N | Missense Mutation (SNP) | VAF 102/235 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as rs774915279; called by muse, mutect2, varscan2
- ADGRA3 | c.3487C>T p.R1163* | Nonsense Mutation (SNP) | VAF 109/495 reads (22%) | catalogued as COSV51562452; called by muse, mutect2, varscan2
- ALOX12B | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); catalogued as rs745541957; called by muse, mutect2, varscan2
- ANKRD30B | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.803); catalogued as rs1421394740; called by muse, mutect2, varscan2
- AP3B2 | c.2565G>A p.S855= (on ENST00000261722; = p.S849= on NM_004644.5) | Splice Region (SNP) | VAF 89/283 reads (31%) | catalogued as rs150157675; called by muse, mutect2, varscan2
- ATP2B2 | c.1915C>T p.P639S (on ENST00000352432; = p.P605S on NM_001683.5) | Missense Mutation (SNP) | VAF 92/400 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1484557674; called by muse, mutect2, varscan2
- ATP8B1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 131/497 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1345769999; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 91/402 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2, varscan2
- BNC2 | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 201/331 reads (61%) | catalogued as COSV66152892; called by muse, mutect2, varscan2
- C2orf16 | c.5836C>T p.P1946S | Missense Mutation (SNP) | VAF 151/437 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.66); catalogued as rs753384616; called by muse, mutect2, varscan2
- CACNA2D3 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55515765; called by muse, mutect2, varscan2
- COL3A1 | c.4211G>A p.G1404E | Missense Mutation (SNP) | VAF 113/424 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58590417; called by muse, mutect2, varscan2
- CRB1 | c.3455G>A p.G1152E | Missense Mutation (SNP) | VAF 120/489 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66329543, COSV66330761; called by muse, mutect2, varscan2
- CSMD3 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 88/351 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1444297700, COSV52103573; called by muse, mutect2, varscan2
- CYP3A7 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100312879; called by muse, mutect2, varscan2
- DCLK3 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 166/561 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs767966305, COSV69362945; called by muse, mutect2, varscan2
- ECEL1 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 104/421 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs781173464; called by muse, mutect2, varscan2
- EGFR | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 89/664 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV51801732; called by muse, mutect2, varscan2
- FAM71E2 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 178/542 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs866110322, COSV52772282, COSV52773313; called by muse, mutect2, varscan2
- FBXL13 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.808); catalogued as rs760076024, COSV57534971; called by muse, mutect2, varscan2
- FGD5 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 187/622 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs1228597882; called by muse, varscan2
- GID4 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as rs866971433; called by muse, mutect2, varscan2
- GZMM | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 126/351 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); catalogued as rs556049813; called by muse, mutect2, varscan2
- HIVEP3 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 150/582 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV56015347; called by muse, mutect2, varscan2
- IFITM3 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV60248879; called by muse, mutect2, varscan2
- IGKV1-6 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 110/398 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1289742499; called by muse, mutect2, varscan2
- IRAK3 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1187059318; called by muse, mutect2, varscan2
- KIF1C | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs571606260, COSV100297273; called by muse, mutect2, varscan2
- KMT2D | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 143/471 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs1159611979, COSV56433189; called by muse, mutect2, varscan2
- KRT33B | c.923G>A p.S308N | Missense Mutation (SNP) | VAF 162/682 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs140145811; called by muse, mutect2, varscan2
- MBP | c.707C>T p.S236L (on ENST00000355994 / NM_001025101.2; = p.S129L on NM_002385.3) | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as COSV62828653; called by muse, mutect2, varscan2
- NFATC3 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 116/488 reads (24%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.528); catalogued as rs1451951342; called by muse, mutect2, varscan2
- NLRP13 | c.2222C>T p.S741F | Missense Mutation (SNP) | VAF 133/412 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.276); catalogued as rs771533652; called by muse, mutect2, varscan2
- NOMO1 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 79/395 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774833781; called by muse, mutect2, varscan2
- NTRK2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 284/466 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV52876588; called by muse, mutect2, varscan2
- OR5L2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65724647; called by muse, mutect2, varscan2
- OSBPL1A | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 78/353 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.627); catalogued as rs755434636; called by muse, mutect2, varscan2
- PRKDC | c.5870A>G p.N1957S | Missense Mutation (SNP) | VAF 105/418 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV58056717; called by muse, mutect2, varscan2
- PRR14L | c.5963G>T p.C1988F | Missense Mutation (SNP) | VAF 127/414 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1401166871; called by muse, mutect2, varscan2
- PRR23C | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 174/545 reads (32%) | catalogued as rs768854745; called by muse, mutect2, varscan2
- PSG7 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 148/602 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1201678064, COSV68445773; called by muse, varscan2
- RALGAPB | c.4375C>T p.R1459W | Missense Mutation (SNP) | VAF 115/407 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs929881882, COSV99485284; called by muse, mutect2, varscan2
- RB1 | c.2234A>C p.K745T | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57326674; called by muse, mutect2, varscan2
- RICTOR | c.3851C>T p.S1284L | Missense Mutation (SNP) | VAF 145/354 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as rs757900166, COSV57126923; called by muse, mutect2, varscan2
- RIMS2 | c.2449C>T p.L817F (on ENST00000666250 / NM_001348490.2; = p.L625F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/505 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51698166; called by muse, mutect2, varscan2
- SALL1 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 96/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51753548; called by muse, mutect2, varscan2
- SCTR | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1488194173, COSV50028107; called by muse, mutect2, varscan2
- SKAP1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 171/597 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); catalogued as COSV61147588; called by muse, mutect2, varscan2
- SLC24A4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs748090494, COSV100104560; called by muse, mutect2, varscan2
- SLC35G3 | c.980A>G p.N327S | Missense Mutation (SNP) | VAF 136/517 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as rs1470272473; called by muse, mutect2, varscan2
- SLC4A10 | c.2270G>A p.R757Q (on ENST00000446997 / NM_001354461.2; = p.R727Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs769463278, COSV55788128; called by muse, mutect2, varscan2
- SLC9C1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs779690767, COSV59885462; called by muse, mutect2, varscan2
- SMAD2 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236865589; called by muse, mutect2, varscan2
- SMPD3 | c.146C>G p.A49G | Missense Mutation (SNP) | VAF 132/577 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1193965905, COSV54712039; called by muse, mutect2, varscan2
- SPDYE16 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs1376065672; called by muse, mutect2, varscan2
- TONSL | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV101340204; called by muse, mutect2, varscan2
- UNC5C | c.2363T>C p.L788P | Missense Mutation (SNP) | VAF 150/550 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs756203732; called by muse, mutect2, varscan2
- WSCD1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 89/398 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764676850; called by muse, mutect2, varscan2
- ZNF750 | c.1816G>A p.G606S | Missense Mutation (SNP) | VAF 181/635 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs762687130, COSV99489770; called by muse, mutect2, varscan2
- ZNF786 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 89/436 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs773066448, COSV60277292; called by muse, mutect2, varscan2
- ZYG11A | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as rs934304733; called by muse, mutect2, varscan2
- ADGRF2 | c.1033C>T p.P345S (on ENST00000296862 / NM_001368115.2; = p.P277S on NM_153839.7) | Missense Mutation (SNP) | VAF 118/397 reads (30%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP30 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 122/556 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB4 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 364/776 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ATP7B | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 133/363 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ATP8B1 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BPNT2 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, varscan2
- C14orf93 | c.105_115del p.Q36Sfs*32 | Frame Shift Del (DEL) | VAF 107/429 reads (25%) | called by mutect2, pindel, varscan2
- C2orf16 | c.2996G>A p.G999E | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CC2D2B | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- CCDC114 | c.1925T>A p.L642H | Missense Mutation (SNP) | VAF 158/582 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CFAP65 | c.3763G>A p.V1255M | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD7 | c.3960C>A p.D1320E | Missense Mutation (SNP) | VAF 115/383 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CHST13 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 134/482 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CNGA1 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL6A5 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 99/408 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL7A1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CSMD1 | c.2449G>A p.D817N (on ENST00000520002; = p.D816N on NM_033225.6) | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCTN1 | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 92/407 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- DDX5 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 123/412 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DLGAP1 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 88/344 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- DNAH10 | c.12502G>A p.D4168N (on ENST00000409039; = p.D4107N on NM_207437.3) | Missense Mutation (SNP) | VAF 170/633 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- DOP1A | c.3941C>A p.S1314* | Nonsense Mutation (SNP) | VAF 121/437 reads (28%) | called by muse, mutect2, varscan2
- DSCAML1 | c.1445G>A p.G482E (on ENST00000321322; = p.G422E on NM_020693.4) | Missense Mutation (SNP) | VAF 187/453 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ELMOD1 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 129/355 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FBXO28 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 314/567 reads (55%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FREM3 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 170/606 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA6 | c.1234G>T p.G412* | Nonsense Mutation (SNP) | VAF 192/533 reads (36%) | called by muse, mutect2, varscan2
- GPBP1 | c.1364C>G p.T455S | Missense Mutation (SNP) | VAF 128/345 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HECW1 | c.2416C>T p.H806Y | Missense Mutation (SNP) | VAF 276/477 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- HIVEP1 | c.7489A>G p.N2497D | Missense Mutation (SNP) | VAF 126/510 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSF1 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.296); called by mutect2, varscan2
- HSPB1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 180/944 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- IFI16 | c.2116G>A p.E706K (on ENST00000295809 / NM_001364867.2; = p.E650K on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/533 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- IFITM3 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRS1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 175/621 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- JAG1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 202/714 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 215/746 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRIQ3 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- LRTM1 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, varscan2
- LTBP2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 130/442 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAML3 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 223/742 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- MARVELD3 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MGAM2 | c.2241G>T p.R747S | Missense Mutation (SNP) | VAF 165/414 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MTTP | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 107/379 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MYH14 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 114/418 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO7B | c.4508C>T p.S1503F | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T12 | c.689A>G p.E230G | Missense Mutation (SNP) | VAF 437/753 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR4D11 | c.94T>G p.C32G | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCLO | c.10282G>A p.E3428K | Missense Mutation (SNP) | VAF 133/694 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PDE1A | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 126/423 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- PDE1C | c.305T>A p.V102D | Missense Mutation (SNP) | VAF 552/934 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDPR | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 85/363 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHACTR1 | c.369G>C p.W123C | Missense Mutation (SNP) | VAF 119/444 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIGT | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 120/446 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- PKD1 | c.8957A>G p.D2986G | Missense Mutation (SNP) | VAF 96/317 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- PLA2G12B | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHM2 | c.1193T>G p.M398R | Missense Mutation (SNP) | VAF 136/497 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- POLA1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 117/192 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTEN | c.491dup p.V166Sfs*14 | Frame Shift Ins (INS) | VAF 70/239 reads (29%) | called by mutect2, pindel, varscan2
- PTPRN2 | c.2425C>T p.H809Y | Missense Mutation (SNP) | VAF 90/456 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RORC | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 162/792 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RYR2 | c.766_773+3del p.X256_splice | Splice Site (DEL) | VAF 143/358 reads (40%) | called by mutect2, pindel, varscan2
- SERPINA6 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 114/408 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- SFPQ | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 105/386 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SLC8A1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 116/369 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TMX3 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TPTE | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TREML2 | c.881T>A p.M294K | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TTC30A | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 89/332 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TTC34 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 171/543 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2I | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 65/323 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UNC13D | c.1407G>T p.W469C | Missense Mutation (SNP) | VAF 124/399 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZC3H12C | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 141/348 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZNF648 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 103/615 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF99 | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF99 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ACOX2 | c.105G>A p.R35= | Silent (SNP) | VAF 126/462 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.2829C>T p.S943= (on ENST00000398564; = p.S918= on NM_014629.4) | Silent (SNP) | VAF 122/444 reads (27%) | catalogued as COSV50679724; called by muse, mutect2, varscan2
- ASF1B | c.570C>T p.I190= | Silent (SNP) | VAF 133/351 reads (38%) | called by muse, mutect2, varscan2
- BRINP2 | c.453C>T p.T151= | Silent (SNP) | VAF 69/381 reads (18%) | catalogued as COSV64176874; called by muse, mutect2, varscan2
- C20orf202 | c.18C>T p.I6= | Silent (SNP) | VAF 86/302 reads (28%) | called by muse, mutect2, varscan2
- C3 | c.3942A>G p.E1314= | Silent (SNP) | VAF 101/267 reads (38%) | called by muse, mutect2, varscan2
- C9orf116 | c.309G>A p.L103= (on ENST00000429260 / NM_001048265.2; = p.W88* on NM_144654.3) | Silent (SNP) | VAF 155/503 reads (31%) | catalogued as rs1375189581; called by muse, mutect2, varscan2
- CARD10 | c.609G>A p.K203= | Silent (SNP) | VAF 344/549 reads (63%) | catalogued as rs1055983270; called by muse, mutect2, varscan2
- CCDC114 | c.1926C>T p.L642= | Silent (SNP) | VAF 159/588 reads (27%) | catalogued as rs779297766, COSV59556235; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5079C>T p.D1693= | Silent (SNP) | VAF 115/269 reads (43%) | catalogued as rs965761601, COSV62575236; called by muse, mutect2, varscan2
- CDX4 | c.351C>T p.G117= | Silent (SNP) | VAF 202/358 reads (56%) | called by muse, mutect2, varscan2
- CIB4 | c.432G>A p.T144= | Silent (SNP) | VAF 87/322 reads (27%) | catalogued as rs370261225; called by muse, mutect2, varscan2
- CLPTM1 | c.189C>T p.I63= | Silent (SNP) | VAF 98/402 reads (24%) | called by muse, mutect2, varscan2
- CREB5 | c.630G>A p.G210= (on ENST00000357727 / NM_182898.4; = p.G203= on NM_004904.3) | Silent (SNP) | VAF 439/713 reads (62%) | catalogued as rs1009575305; called by muse, mutect2, varscan2
- CRYBG2 | c.2034G>A p.Q678= | Silent (SNP) | VAF 114/383 reads (30%) | called by muse, mutect2, varscan2
- CSMD2 | c.1155A>G p.K385= | Silent (SNP) | VAF 120/386 reads (31%) | called by muse, mutect2, varscan2
- CYTIP | c.852C>T p.C284= | Silent (SNP) | VAF 125/510 reads (25%) | called by muse, mutect2, varscan2
- DLGAP2 | c.2103C>T p.I701= | Silent (SNP) | VAF 150/574 reads (26%) | called by muse, mutect2, varscan2
- DNAH5 | c.4083C>T p.P1361= | Silent (SNP) | VAF 82/234 reads (35%) | catalogued as rs149691390; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFCAB14 | c.1371G>A p.Q457= | Silent (SNP) | VAF 147/510 reads (29%) | called by muse, mutect2, varscan2
- FLRT2 | c.1053G>A p.R351= | Silent (SNP) | VAF 131/473 reads (28%) | catalogued as rs1566763272, COSV100420263; called by muse, mutect2, varscan2
- GRHL3 | c.1623G>A p.R541= (on ENST00000350501 / NM_198174.3; = p.R546= on NM_021180.3) | Silent (SNP) | VAF 102/392 reads (26%) | called by muse, mutect2, varscan2
- HECW1 | c.2415C>T p.L805= | Silent (SNP) | VAF 274/473 reads (58%) | called by muse, mutect2, varscan2
- HSF1 | c.1086C>T p.P362= | Silent (SNP) | VAF 111/346 reads (32%) | called by mutect2, varscan2
- IFI27L1 | c.54C>T p.V18= | Silent (SNP) | VAF 179/635 reads (28%) | catalogued as rs1040733075; called by muse, mutect2, varscan2
- IGHV3-64 | c.123C>T p.S41= | Silent (SNP) | VAF 137/511 reads (27%) | called by muse, mutect2, varscan2
- IL7R | c.1353C>T p.T451= | Silent (SNP) | VAF 80/214 reads (37%) | catalogued as rs201947153, COSV57409660; called by muse, mutect2, varscan2
- ISM2 | c.540C>T p.T180= | Silent (SNP) | VAF 116/413 reads (28%) | catalogued as COSV53634248; called by muse, mutect2, varscan2
- JAG1 | c.309G>A p.G103= | Silent (SNP) | VAF 204/719 reads (28%) | called by muse, mutect2, varscan2
- KIF1C | c.1449C>T p.V483= | Silent (SNP) | VAF 104/428 reads (24%) | catalogued as COSV100297271; called by muse, mutect2, varscan2
- LAMA1 | c.6534C>T p.F2178= | Silent (SNP) | VAF 121/436 reads (28%) | catalogued as COSV67534784; called by muse, mutect2, varscan2
- LMLN | c.369G>A p.A123= | Silent (SNP) | VAF 76/315 reads (24%) | catalogued as rs749690580, COSV57602085; called by muse, mutect2, varscan2
- LPAR1 | c.888C>T p.F296= | Silent (SNP) | VAF 142/363 reads (39%) | catalogued as COSV62687549; called by muse, mutect2, varscan2
- LPAR2 | c.1047C>T p.S349= | Silent (SNP) | VAF 96/225 reads (43%) | called by muse, mutect2, varscan2
- LRIT1 | c.348G>A p.G116= | Silent (SNP) | VAF 143/399 reads (36%) | called by muse, mutect2, varscan2
- LRTM1 | c.255C>T p.S85= | Silent (SNP) | VAF 107/413 reads (26%) | catalogued as COSV55540712; called by muse, varscan2
- MAST3 | c.1791C>T p.I597= | Silent (SNP) | VAF 74/174 reads (43%) | catalogued as rs779206753, COSV53227020; called by muse, mutect2, varscan2
- MEIS3 | c.204C>A p.L68= | Silent (SNP) | VAF 130/445 reads (29%) | called by muse, mutect2, varscan2
- MGAM2 | c.2016C>T p.L672= | Silent (SNP) | VAF 278/645 reads (43%) | called by muse, mutect2, varscan2
- MMUT | c.1233C>T p.I411= | Silent (SNP) | VAF 147/537 reads (27%) | catalogued as rs1410409444; called by muse, mutect2, varscan2
- NUPR2 | c.96G>A p.L32= | Silent (SNP) | VAF 103/758 reads (14%) | called by muse, mutect2, varscan2
- OR10J3 | c.154C>T p.L52= | Silent (SNP) | VAF 153/659 reads (23%) | catalogued as rs1306304533; called by muse, mutect2, varscan2
- OR10J3 | c.153C>T p.R51= | Silent (SNP) | VAF 151/657 reads (23%) | called by muse, mutect2, varscan2
- OR2A7 | c.69G>A p.Q23= | Silent (SNP) | VAF 100/816 reads (12%) | called by muse, mutect2, varscan2
- PCNA | c.741A>G p.L247= | Silent (SNP) | VAF 69/264 reads (26%) | called by muse, mutect2, varscan2
- PDLIM3 | c.132C>T p.P44= (on ENST00000284770 / NM_001257963.1; = p.P123= on NM_014476.6) | Silent (SNP) | VAF 111/394 reads (28%) | called by muse, mutect2, varscan2
- PKD1 | c.8511C>T p.G2837= | Silent (SNP) | VAF 132/447 reads (30%) | catalogued as rs750550230; called by muse, mutect2, varscan2
- PLCH1 | c.1059A>G p.G353= (on ENST00000340059 / NM_001130960.2; = p.G365= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/288 reads (25%) | catalogued as rs1189478425; called by muse, mutect2, varscan2
- PRR22 | c.939C>T p.A313= | Silent (SNP) | VAF 130/328 reads (40%) | catalogued as rs1271855011, COSV104395914; called by muse, mutect2, varscan2
- PSIP1 | c.240T>C p.G80= | Silent (SNP) | VAF 89/192 reads (46%) | catalogued as rs755842793; called by muse, mutect2, varscan2
- RALGAPB | c.4374C>T p.R1458= | Silent (SNP) | VAF 114/404 reads (28%) | catalogued as rs774343691; called by muse, mutect2, varscan2
- RB1CC1 | c.429A>G p.E143= | Silent (SNP) | VAF 132/500 reads (26%) | called by muse, mutect2, varscan2
- REG3A | c.207G>A p.Q69= | Silent (SNP) | VAF 97/388 reads (25%) | catalogued as rs770807563, COSV59410966; called by muse, mutect2, varscan2
- RUNX1T1 | c.135G>A p.V45= (on ENST00000265814 / NM_001198628.1; = p.V18= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/469 reads (21%) | catalogued as rs750863639, COSV56161965; called by muse, mutect2, varscan2
- SALL1 | c.909C>T p.L303= | Silent (SNP) | VAF 113/467 reads (24%) | catalogued as rs770978250; called by muse, mutect2, varscan2
- SAMHD1 | c.396C>T p.L132= | Silent (SNP) | VAF 141/477 reads (30%) | catalogued as rs1216724127, COSV99484043; called by muse, mutect2, varscan2
- SEMA6C | c.2754C>T p.S918= | Silent (SNP) | VAF 174/696 reads (25%) | catalogued as COSV59008717; called by muse, mutect2, varscan2
- SF3B3 | c.2565C>T p.P855= | Silent (SNP) | VAF 132/487 reads (27%) | called by muse, mutect2, varscan2
- SGSM2 | c.924G>C p.L308= | Silent (SNP) | VAF 95/300 reads (32%) | called by muse, mutect2, varscan2
- SMAD3 | c.477C>T p.S159= | Silent (SNP) | VAF 139/471 reads (30%) | called by muse, mutect2, varscan2
- SPATC1 | c.624G>A p.G208= | Silent (SNP) | VAF 157/590 reads (27%) | called by muse, mutect2, varscan2
- SUMF2 | c.696C>T p.V232= (on ENST00000652303; = p.V213= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/941 reads (13%) | catalogued as rs748944901, COSV99305409; called by muse, mutect2, varscan2
- SYNJ2 | c.3309G>A p.R1103= | Silent (SNP) | VAF 122/418 reads (29%) | catalogued as COSV62899570; called by muse, mutect2, varscan2
- TNFRSF9 | c.384G>A p.Q128= | Silent (SNP) | VAF 74/355 reads (21%) | called by muse, mutect2, varscan2
- TRIM71 | c.816C>T p.P272= | Silent (SNP) | VAF 123/416 reads (30%) | called by muse, varscan2
- VCAM1 | c.894G>A p.G298= | Silent (SNP) | VAF 62/204 reads (30%) | called by muse, mutect2, varscan2
- WSCD1 | c.678C>T p.D226= | Silent (SNP) | VAF 90/401 reads (22%) | catalogued as rs755513214; called by muse, mutect2, varscan2
- XKR6 | c.1272C>T p.I424= | Silent (SNP) | VAF 133/518 reads (26%) | catalogued as rs759258980, COSV58656328; called by muse, mutect2, varscan2
- ANKS1B | c.2420-68G>A | Intron (SNP) | VAF 120/419 reads (29%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57610577 G>A | 5'Flank (SNP) | VAF 89/323 reads (28%) | called by muse, mutect2, varscan2
- CASP10 | c.685-3268T>A | Intron (SNP) | VAF 112/384 reads (29%) | catalogued as rs1180390007; called by muse, mutect2, varscan2
- CNOT3 | c.2037+62C>T | Intron (SNP) | VAF 159/537 reads (30%) | called by muse, mutect2, varscan2
- FBRS | chr16:30659790 C>T | 5'Flank (SNP) | VAF 212/746 reads (28%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11158T>C | Intron (SNP) | VAF 164/560 reads (29%) | called by muse, mutect2, varscan2
- MAPK4 | c.547-10389C>T | Intron (SNP) | VAF 100/353 reads (28%) | catalogued as rs866638997; called by muse, mutect2, varscan2
- S1PR3 | c.-148+127G>T | Intron (SNP) | VAF 305/574 reads (53%) | catalogued as rs948586009; called by muse, mutect2, varscan2
- SYNGAP1 | c.296-228C>T | Intron (SNP) | VAF 118/428 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.10360+2130C>T | Intron (SNP) | VAF 103/396 reads (26%) | catalogued as COSV100597253, COSV100605850, COSV59878227; called by muse, mutect2, varscan2
